Somatic mutation profile of tumor specimen TCGA-FC-A66V-01A (aliquot TCGA-FC-A66V-01A-21D-A30E-08) from TCGA case TCGA-FC-A66V, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 74.7 years (27,282 days).
Specimen TCGA-FC-A66V-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8b399944-5afd-407b-b4e0-6a714d132638.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FC-A66V-10A (Blood Derived Normal), aliquot TCGA-FC-A66V-10A-01D-A30H-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9efdbd26-cadc-428a-8989-cf6a71fcc3e1

The open-access MAF lists 2 somatic variants for this specimen: 2 silent.
By variant classification: Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARHGEF26 | c.1953C>A p.S651= | Silent (SNP) | VAF 3/50 reads (6%) | catalogued as COSV62843918; called by muse, mutect2
- NISCH | c.2503C>T p.L835= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as COSV61901719; called by muse, mutect2
